Somatic mutation profile of tumor specimen ASCProject_0145_T2_WES (aliquot ASCProject_0145_T2_WES_1) from CMI case ASCProject_0145, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 28.0 years (10,215 days).
Specimen ASCProject_0145_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68af14fc-efe2-415f-a23f-0b538e3567a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0145_SALIVA (Saliva), aliquot ASCProject_0145_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdbcfbc3-1bec-4266-b5a7-fea8173b08da

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C9orf64 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1236138052, COSV59032500; called by muse, mutect2, varscan2
- CUL1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as COSV57388811; called by muse, mutect2, varscan2
- OBSCN | c.20476C>A p.L6826M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV100804090; called by muse, mutect2, varscan2
- WNT5A | c.1055C>T p.T352M | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as rs755298573, COSV52837872; called by muse, mutect2, varscan2
- XCL2 | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63194760; called by muse, mutect2, varscan2
- CENPS-CORT | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- CRYBG1 | c.2537A>G p.D846G | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CYP2E1 | c.914G>T p.S305I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EXPH5 | c.4171A>T p.S1391C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- HUWE1 | c.9961A>G p.T3321A | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IYD | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDR | c.2193C>G p.D731E | Missense Mutation (SNP) | VAF 226/1216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDR | c.2110_2112del p.N704del | In Frame Del (DEL) | VAF 104/1048 reads (10%) | called by mutect2, pindel
- KIAA1522 | c.296C>G p.T99R (on ENST00000373480 / NM_001198972.2; = p.T158R on NM_020888.3) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- OR7A5 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- TTLL8 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ZFP36L1 | c.404dup p.C135Wfs*46 | Frame Shift Ins (INS) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- NXPE1 | c.636C>A p.G212= (on ENST00000424269; = p.G70= on NM_152315.5) | Silent (SNP) | VAF 63/244 reads (26%) | catalogued as rs750154956; called by muse, mutect2, varscan2
- SLC4A1 | c.382C>T p.L128= | Silent (SNP) | VAF 52/235 reads (22%) | called by muse, mutect2, varscan2
